Somatic mutation profile of tumor specimen MP2PRT-PATJIU-TMP1-A (aliquot MP2PRT-PATJIU-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PATJIU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.0 years (1,113 days).
Specimen MP2PRT-PATJIU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 689212c9-2186-441c-9d97-d550db4f9d1d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATJIU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATJIU-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e811c785-6590-4757-97f8-121229192d0e

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 7, Silent 4, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EBF4 | c.490C>T p.R164W (on ENST00000609451; = p.R160W on NM_001110514.1) | Missense Mutation (SNP) | VAF 20/292 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV61355783; called by muse, mutect2
- FLOT1 | c.357G>T p.E119D | Missense Mutation (SNP) | VAF 46/262 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs1317259954; called by mutect2, varscan2
- GAL3ST4 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 103/402 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs190271844, COSV57586628; called by muse, mutect2, varscan2
- PHACTR3 | c.1003C>T p.R335W | Missense Mutation (SNP) | VAF 93/317 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.918); catalogued as rs570660590, COSV63027554; called by muse, mutect2, varscan2
- PLVAP | c.655C>T p.Q219* | Nonsense Mutation (SNP) | VAF 134/474 reads (28%) | catalogued as rs749038957; called by muse, mutect2, varscan2
- RAB40AL | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 26/563 reads (5%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.893); catalogued as COSV54433627; called by muse, mutect2
- SLC6A14 | c.1390G>A p.V464I | Missense Mutation (SNP) | VAF 20/284 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs376654431; called by muse, mutect2
- NOL10 | c.184A>G p.K62E | Missense Mutation (SNP) | VAF 43/252 reads (17%) | SIFT tolerated (0.3); PolyPhen benign (0.103); called by muse, mutect2, varscan2
- DST | c.13719G>A p.Q4573= (on ENST00000361203 / NM_001374722.1; = p.Q2161= on NM_015548.5) | Silent (SNP) | VAF 56/367 reads (15%) | called by muse, mutect2, varscan2
- LAMA5 | c.9498G>A p.A3166= | Silent (SNP) | VAF 71/395 reads (18%) | catalogued as rs776827129, COSV53362189; called by muse, mutect2, varscan2
- MUC13 | c.126A>G p.A42= | Silent (SNP) | VAF 16/450 reads (4%) | called by muse, mutect2
- RAD50 | c.396G>A p.K132= | Silent (SNP) | VAF 38/248 reads (15%) | catalogued as rs764801872; ClinVar: likely benign; called by muse, mutect2, varscan2
